Somatic mutation profile of tumor specimen 0DZ6H3 from CCDI case PBCTFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.5 years (2,015 days).
Specimen 0DZ6H3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c4869b3-6c54-4248-93dc-f24019ddc29c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ6FG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c08af64-a07a-44a1-b26a-4fd9508a40de

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 4, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3AR1 | c.978C>A p.D326E | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.022); catalogued as rs1453300461, COSV50817778; called by muse, mutect2, varscan2
- CDH9 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 183/624 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs138749280; called by muse, mutect2, varscan2
- CEMIP | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs780439812, COSV54992807; called by muse, mutect2, varscan2
- PFN3 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1307421174, COSV53692132; called by muse, mutect2, varscan2
- PIDD1 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs547882558; called by muse, mutect2, varscan2
- SUGP2 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs754522373; called by muse, mutect2, varscan2
- TSHZ1 | c.2524G>A p.D842N (on ENST00000580243 / NM_001308210.2; = p.D797N on NM_005786.6) | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1225312620, COSV59005256; called by muse, mutect2, varscan2
- ZNF519 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs141714861, COSV73913203; called by mutect2, varscan2
- CCDC96 | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DCDC1 | c.1505A>C p.N502T | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DYRK2 | c.1141A>G p.T381A (on ENST00000344096 / NM_006482.3; = p.T308A on NM_003583.4) | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRD1 | c.2110C>A p.L704M | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- MAIP1 | c.870A>C p.L290F | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- MS4A14 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH7 | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- NFKBIA | c.479_481del p.V160del | In Frame Del (DEL) | VAF 82/209 reads (39%) | called by mutect2, varscan2
- PKP2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SPEF2 | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 150/527 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CNR2 | c.882C>A p.V294= | Silent (SNP) | VAF 91/119 reads (76%) | called by muse, mutect2, varscan2
- DENND4C | c.3339G>A p.S1113= (on ENST00000434457 / NM_001330640.2; = p.S1064= on NM_017925.7) | Silent (SNP) | VAF 133/345 reads (39%) | catalogued as rs772506615, COSV63008578; called by muse, mutect2, varscan2
- GREB1L | c.2892G>A p.S964= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as rs1464771852, COSV52569809; called by muse, mutect2, varscan2
- MYCBP2 | c.2226C>T p.A742= (on ENST00000357337; = p.A780= on NM_015057.5) | Silent (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- CCDC144A | c.2105+94G>A | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ICAM1 | c.1426+15G>A | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs200051692; called by mutect2, varscan2
- ING3 | c.267+559C>T | Intron (SNP) | VAF 127/379 reads (34%) | catalogued as COSV100187444; called by muse, mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- SNAPIN | c.*9C>T | 3'UTR (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- ZNF707 | c.142+53T>C | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
